Somatic mutation profile of tumor specimen MP2PRT-PAVSRL-TMP1-A (aliquot MP2PRT-PAVSRL-TMP1-A-1-0-D-A83Q-36) from MP2PRT case MP2PRT-PAVSRL, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.7 years (986 days).
Specimen MP2PRT-PAVSRL-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9828a405-e91c-44b6-8aaf-41f3354a785f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVSRL-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVSRL-NB1-A-1-0-D-A83Q-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/898a8195-9fda-4882-9f51-44f4e00019e4

The open-access MAF lists 17 somatic variants for this specimen: 15 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 13, Silent 2, In Frame Del 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FLT3 | c.2524T>C p.Y842H | Missense Mutation (SNP) | VAF 28/239 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519762, COSV54057460; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- KRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 35/205 reads (17%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.44); catalogued as rs112445441, CM125166, COSV55497357, COSV55497388, COSV55522580; ClinVar: likely pathogenic / pathogenic; called by muse, varscan2
- ALDH1L1 | c.1454G>A p.R485Q | Missense Mutation (SNP) | VAF 68/151 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs753247080, COSV56419246; called by muse, mutect2, varscan2
- AP2A2 | c.1061C>T p.T354M | Missense Mutation (SNP) | VAF 46/468 reads (10%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.945); catalogued as rs768484784; called by muse, mutect2, varscan2
- CBY2 | c.1054G>A p.G352S | Missense Mutation (SNP) | VAF 137/343 reads (40%) | SIFT tolerated (0.64); PolyPhen benign (0.005); catalogued as rs778108248, COSV60120103; called by muse, mutect2, varscan2
- FBN1 | c.2456G>C p.G819A | Missense Mutation (SNP) | VAF 87/237 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.983); catalogued as CM100094; called by muse, mutect2, varscan2
- MTCL1 | c.1979G>A p.R660Q (on ENST00000306329 / NM_001378206.1; = p.R300Q on NM_015210.4) | Missense Mutation (SNP) | VAF 99/408 reads (24%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.588); catalogued as rs766887517; called by muse, mutect2, varscan2
- PLEKHM2 | c.632C>T p.A211V | Missense Mutation (SNP) | VAF 50/149 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.546); catalogued as rs373741350; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- POU3F2 | c.219_236del p.G83_G88del | In Frame Del (DEL) | VAF 86/490 reads (18%) | catalogued as rs757811015; called by mutect2, varscan2
- RAB36 | c.853G>A p.A285T | Missense Mutation (SNP) | VAF 95/219 reads (43%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.832); catalogued as rs776616565; called by muse, mutect2, varscan2
- SHCBP1L | c.1076G>A p.R359Q | Missense Mutation (SNP) | VAF 49/110 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs777059000, COSV62356732; called by muse, mutect2, varscan2
- SHROOM3 | c.2152C>T p.R718W | Missense Mutation (SNP) | VAF 34/542 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs774215303, COSV56026251, COSV99934987; called by muse, mutect2
- SLC6A1 | c.1559C>T p.T520M | Missense Mutation (SNP) | VAF 60/154 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.885); catalogued as rs372892801; called by muse, mutect2, varscan2
- ZNF726 | c.1298C>T p.A433V | Missense Mutation (SNP) | VAF 22/196 reads (11%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.997); catalogued as rs1568380661; called by muse, mutect2, varscan2
- PLEKHA8 | c.1300dup p.N434Kfs*2 (on ENST00000449726 / NM_001197026.2; = p.R434Kfs*49 on NM_032639.4) | Frame Shift Ins (INS) | VAF 17/152 reads (11%) | called by mutect2, pindel, varscan2
- NEMP2 | c.177C>T p.S59= | Silent (SNP) | VAF 87/206 reads (42%) | catalogued as COSV58109977; called by muse, mutect2, varscan2
- ROS1 | c.1200C>T p.I400= | Silent (SNP) | VAF 76/268 reads (28%) | catalogued as rs1002056236, COSV100877679; called by muse, mutect2, varscan2
